Somatic mutation profile of tumor specimen 2ed8beb2-bc63-4bad-b5fe-1916a0 (aliquot 2ed8beb2-bc63-4bad-b5fe-1916a0_D6) from CPTAC case 02OV023, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 2ed8beb2-bc63-4bad-b5fe-1916a0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683a9167-a40b-4ad5-aed1-5a915e5ebe9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7d942a6f-236e-4659-89a2-6711ae (Blood Derived Normal), aliquot 7d942a6f-236e-4659-89a2-6711ae_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec8d505e-789a-4057-a2ca-b3faf4721835

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Intron 3, Splice Site 2, 3'UTR 1, In Frame Del 1, Translation Start Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG13 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99322343; called by muse, mutect2, varscan2
- ARHGAP35 | c.1997A>T p.N666I | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV68330921; called by muse, varscan2
- FLG | c.3843C>A p.D1281E | Missense Mutation (SNP) | VAF 485/972 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs545397624, COSV64242640; called by mutect2, varscan2
- GUCY2D | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1431677230, COSV54695776; called by muse, mutect2, varscan2
- HBP1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV56016728; called by muse, mutect2, varscan2
- LSP1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs764746759; called by muse, mutect2, varscan2
- MRPL54 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV57519362; called by muse, mutect2, varscan2
- MYH1 | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56853005; called by muse, mutect2, varscan2
- PUF60 | c.943C>T p.P315S (on ENST00000526683 / NM_001362896.2; = p.P298S on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as rs940333309; called by muse, mutect2, varscan2
- SPATA31A3 | c.3694G>A p.V1232I | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1422472078; called by muse, mutect2, varscan2
- TBC1D21 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV55996709; called by muse, mutect2, varscan2
- TCF25 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs927664285, COSV54525201; called by muse, mutect2, varscan2
- C4orf54 | c.3064A>T p.I1022F | Missense Mutation (SNP) | VAF 131/402 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CBL | c.870-1G>T p.X290_splice | Splice Site (SNP) | VAF 102/298 reads (34%) | called by mutect2, varscan2
- CRYBG3 | c.7153-10_7164del p.X2385_splice | Splice Site (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- EAPP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENOX2 | c.1261_1273del p.L421Sfs*8 (on ENST00000338144 / NM_001382520.1; = p.L392Sfs*8 on NM_006375.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/135 reads (30%) | called by mutect2, pindel, varscan2
- FGFR4 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR83 | c.1222T>A p.S408T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- HMCN2 | c.13177C>A p.P4393T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICOS | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by mutect2, varscan2
- OR12D3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR2J3 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- POLA1 | c.2084T>G p.I695S | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PRRC2B | c.5152_5160del p.A1718_K1720del | In Frame Del (DEL) | VAF 65/144 reads (45%) | called by mutect2, pindel, varscan2
- RIMS4 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SAMD7 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC38A4 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, varscan2
- SPNS2 | c.735_736insAT p.Y246Ifs*8 | Frame Shift Ins (INS) | VAF 73/149 reads (49%) | called by mutect2, varscan2*
- ARHGEF9 | c.1191G>A p.K397= | Silent (SNP) | VAF 109/402 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.3582C>T p.I1194= (on ENST00000297405 / NM_001363185.1; = p.I1090= on NM_052900.3) | Silent (SNP) | VAF 141/446 reads (32%) | catalogued as rs201515007, COSV52233054; called by muse, mutect2, varscan2
- CSN3 | c.15T>G p.L5= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV59243681, COSV59244066; called by muse, mutect2
- HCN1 | c.2493C>A p.G831= | Silent (SNP) | VAF 58/186 reads (31%) | called by mutect2, varscan2
- IGHMBP2 | c.2403C>T p.G801= | Silent (SNP) | VAF 82/383 reads (21%) | called by muse, mutect2, varscan2
- MRPL11 | c.300G>A p.G100= | Silent (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- NFX1 | c.3195C>T p.S1065= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as rs761709550; called by muse, mutect2, varscan2
- NIBAN3 | c.1063C>A p.R355= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1187967734; called by muse, mutect2, varscan2
- PCDHGA11 | c.1050C>T p.I350= | Silent (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- ST14 | c.2055C>T p.S685= | Silent (SNP) | VAF 188/575 reads (33%) | catalogued as rs1422820401, COSV53835414; called by muse, mutect2, varscan2
- UNC79 | c.4752C>T p.N1584= (on ENST00000393151 / NM_001346218.2; = p.N1407= on NM_020818.5) | Silent (SNP) | VAF 79/252 reads (31%) | called by muse, mutect2, varscan2
- CXCL12 | c.267-2599C>T | Intron (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- EPS8L2 | c.100+9G>C | Intron (SNP) | VAF 73/243 reads (30%) | called by muse, mutect2, varscan2
- LMO4 | c.*29T>G | 3'UTR (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- RASSF4 | c.63-98C>A | Intron (SNP) | VAF 130/354 reads (37%) | called by muse, mutect2, varscan2
